Somatic mutation profile of tumor specimen TCGA-B8-A54K-01A (aliquot TCGA-B8-A54K-01A-11D-A33K-10) from TCGA case TCGA-B8-A54K, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 61.9 years (22,627 days).
Specimen TCGA-B8-A54K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a69a9d0c-7ea3-4b5d-8f3f-b9bb8a3b77b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-A54K-10A (Blood Derived Normal), aliquot TCGA-B8-A54K-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5ebcd26-f014-4574-a7e5-cc5f5de166cc

The open-access MAF lists 24 somatic variants for this specimen: 14 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 9, Missense Mutation 9, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTHFR | c.236+1G>A p.X79_splice | Splice Site (SNP) | VAF 25/56 reads (45%) | catalogued as rs1057519359, CS163971, COSV100412157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDX60L | c.2471G>A p.G824D | Missense Mutation (SNP) | VAF 154/354 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773129584, COSV99488359; called by muse, mutect2, varscan2
- ERG | c.603C>A p.Y201* | Nonsense Mutation (SNP) | VAF 69/150 reads (46%) | catalogued as COSV99902669; called by muse, mutect2, varscan2
- EXOSC1 | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100602458; called by muse, mutect2, varscan2
- GABRG3 | c.483C>A p.Y161* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as COSV100409598; called by muse, mutect2, varscan2
- MYL12B | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV99410652; called by muse, mutect2, varscan2
- PAGE4 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 124/154 reads (81%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as COSV99489871; called by muse, mutect2, varscan2
- RPS6KA3 | c.1521A>T p.R507S | Missense Mutation (SNP) | VAF 137/168 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV101084641; called by muse, mutect2, varscan2
- SLC13A1 | c.1477A>G p.T493A | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99521422; called by muse, mutect2
- SLC7A2 | c.1585C>G p.L529V (on ENST00000494857 / NM_001370338.1; = p.L568V on NM_003046.6) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as rs774741704, COSV99135749; called by muse, mutect2, varscan2
- TNXB | c.7789C>T p.P2597S (on ENST00000647633; = p.P2350S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.943); catalogued as COSV100926602; called by muse, mutect2
- ZBP1 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs752942618, COSV100473894; called by muse, mutect2, varscan2
- MIDN | c.1389dup p.E464Rfs*65 | Frame Shift Ins (INS) | VAF 92/216 reads (43%) | called by mutect2, varscan2
- PLXNB1 | c.5975del p.N1992Tfs*76 | Frame Shift Del (DEL) | VAF 59/193 reads (31%) | called by mutect2, pindel, varscan2
- A2M | c.501T>A p.I167= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs765569153, COSV100588963; called by muse, mutect2, varscan2
- C3orf22 | c.123C>T p.P41= | Silent (SNP) | VAF 4/86 reads (5%) | catalogued as COSV100559552; called by muse, mutect2
- CENPB | c.1188C>A p.T396= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV100713617; called by muse, mutect2, varscan2
- DCUN1D2 | c.646C>T p.L216= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV60261774; called by muse, mutect2, varscan2
- DLGAP1 | c.816G>A p.P272= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs200721238, COSV100227585; called by muse, mutect2, varscan2
- HROB | c.1923C>T p.F641= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as rs756440846, COSV99809380; called by muse, mutect2, varscan2
- MDN1 | c.1251C>T p.L417= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV101021796; called by muse, mutect2, varscan2
- PFAS | c.1824C>G p.V608= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV100119122; called by muse, mutect2, varscan2
- SH3RF3 | c.1821T>A p.I607= | Silent (SNP) | VAF 72/176 reads (41%) | catalogued as COSV100513705; called by muse, mutect2, varscan2
- HSPB3 | c.*1C>A | 3'UTR (SNP) | VAF 44/98 reads (45%) | catalogued as COSV100115999; called by muse, mutect2, varscan2
